CPTAC case C3N-02944 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/400e94ed-2c26-4ef3-a232-a45781a1bf9f

Demographics
Sex at birth: female; Race: asian; Year of birth: 1955; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Age at diagnosis: 62.0 years (22,648 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 609 days (1.7 years); Progression or recurrence: yes; Days to last follow up: 609 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 265 days; Disease response: Partial Response; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 609 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 391 days (1.1 years); Karnofsky performance status: 40; ECOG performance status: 3.

Other clinical attributes
- Weight: 53 kg; Height: 158 cm; BMI: 21.23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02944-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 154 mg; Time between clamping and freezing: 21 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02944-21: Section location: Pancreatic body and tail; Percent tumor nuclei: 40; Percent necrosis: 5.
- Sample C3N-02944-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 165 mg; Time between clamping and freezing: 21 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02944-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
